CCDI case PBCDXB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/1045109c-d611-4d02-9560-33fc4c38f306

Demographics
Sex at birth: male.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.4 years (6,004 days).

Biospecimens (3 samples)
- Sample 0DPHT1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPHTF: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPHTQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
